Surgical pathology report (de-identified scan), TCGA case TCGA-23-1029, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1029-01B (Primary Tumor).

[page 1 of 4]
Path #:
Pathologist:
Assistant:
Date of Procedure:
Date Received:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. BLADDER TUMOR, BIOPSY:

- High-grade mullerian carcinoma, serous-type

B,C. OMENTUM #1 AND #2, EXCISIONS:

- High-grade mullerian carcinoma, serous-type

D. COLON MESENTERY, EXCISION:

- High-grade mullerian carcinoma, serous-type

E. LEFT OVARY, OOPHORECTOMY:

- High-grade mullerian carcinoma, serous-type, replacing almost the entire ovary

F. RIGHT OVARY, OOPHORECTOMY:

- High-grade mullerian carcinoma, serous-type, replacing almost the entire ovary

G. CUL DE SAC, BIOPSY:

- High-grade mullerian carcinoma, serous-type

H. UTERUS, CERVIX, RIGHT AND LEFT FALLOPIAN TUBES, HYSTERECTOMY WITH BILATERAL SALPINGECTOMY:

- High-grade mullerian carcinoma, serous-type, involving the serosa of uterine corpus, cervix, and right fallopian tube
- Benign non-phasic endometrium
- Cervical mucosa is free of tumor
- Right and left fallopian tube mucosa appears free of tumor

I. ANTERIOR PERITONEUM, BIOPSY:

- High-grade mullerian carcinoma, serous-type

J. RIGHT URETER, BIOPSY:

- High-grade mullerian carcinoma, serous-type

K. FALCIFORM LIGAMENT, EXCISION:

- High-grade mullerian carcinoma, serous-type

pTNM staging: pT3cNxMx

HISTORY: Pelvic mass, ascites, probable ovarian cancer

MICROSCOPIC:

See diagnosis.

Patient Case(s):

[page 2 of 4]
PATH #:

GROSS:

A. BLADDER TUMOR

Labeled with the patient's name, labeled "bladder tumor", and received in formalin is an aggregate of tan firm tissue fragments ranging from 1.0 up to 4.0 cm in greatest dimension and aggregating to 4.5 x 3.2 x 1.0 cm. Representative sections are submitted.

A1. 4

B. OMENTUM #1

Labeled with the patient's name, labeled "omentum #1", and received fresh for frozen section evaluation and subsequently fixed in formalin is a portion of omentum measuring 10.0 x 7.2 x 1.5 cm. Adipose tissue is almost entirely replaced by gray-white rubbery friable tumor. Focal hemorrhage is also noted. Representative sections are submitted.

B1. Frozen section control for FS1 - 1

B2, B3. Additional tumor - 2 each

C. OMENTUM #2

Labeled with the patient's name, labeled "omentum 2", and received in formalin is a portion of omentum measuring 17.5 x 5.0 x 3.0 cm. The adipose tissue is almost entirely replaced by tan-white friable tumor. Representative sections are submitted.

C1, C2. 2 each

D. COLON MESENTERY

Labeled with the patient's name, labeled "colon mesentery", and received in formalin are three portions of mesentery measuring 6.0 to 11.5 cm in greatest dimension. The fatty tissue is approximately 80% replaced by gray-white friable tumor. Sectioning reveals no recognizable lymph nodes. Representative sections are submitted.

D1, D2. 2 each

E. LEFT OVARY

Labeled with the patient's name, labeled "left ovary", and received in formalin is a 300 gram oophorectomy specimen measuring 13.0 x 6.5 x 6.2 cm. The specimen has been previously incised. On opening, the cut surfaces are approximately 60% cystic and 40% solid, with the solid portions consisting of gray-white firm somewhat friable tumor. The cystic areas measure 1.5 to 4.5 cm in greatest dimension and are multiloculated. The cyst linings are mostly pink-tan and smooth except where adjacent to the solid tumor. The solid portion of tumor appears to focally invade through the serosal surface. No normal ovarian parenchyma is seen.

The cyst contents consist of red-brown watery fluid of approximately 300 ml. Focal hemorrhage is also noted within the ovary. No fallopian tube is identified.

Ink key: Serosal surface inked black. Representative sections are submitted.

E1. Solid part of tumor - 1

E2. Solid part of tumor - 1

E3. Solid part of tumor - 1

E4. Solid part of tumor - 1

E5. Hemorrhage - 1

E6-E12. Cyst wall - 3 each

F. RIGHT OVARY

Labeled with the patient's name, labeled "right ovary", and received in formalin is a 180 gram, 9.0 x 7.3 x 5.2 cm oophorectomy specimen. The serosal surface is bosselated and roughened with focal gray-white tumor. Sectioning

[page 3 of 4]
PATH #:

reveals approximately 30% solid gray-white tumor and 70% cystic change. The cyst is partially septated and measures 8.5 x 6.0 x 3.5 cm. No normal ovarian parenchyma is identified. There is one area of bosselation within the cyst measuring 1.8 x 1.5 x 0.9 cm with an otherwise smooth pink-tan inner lining.

No normal ovarian parenchyma is seen. No tube is identified.

Ink key: Serosal surface inked black.

Representative sections are submitted.

F1. Solid portion of tumor - 2

F2. Solid portion of tumor - 2

F3. Solid portion of tumor - 1

F4. Solid portion of tumor - 1

F5-F9. Cyst wall - 3 each

G. CUL-DE-SAC

Labeled with the patient's name, labeled "cul-de-sac", and received in formalin is an aggregate of pink-tan friable tumor fragments measuring 1.0 to 4.2 cm in greatest dimension and aggregating to 4.7 x 4.0 x 0.8 cm.

Representative sections are submitted.

G1. 3

H. UTERUS AND TUBES RIGHT AND LEFT

Labeled with the patient's name, labeled "uterus and tubes right and left", and received in formalin is a 100 gram total hysterectomy specimen with attached bilateral tubes. There is scant attached pink-tan soft tissue. The uterus measures 8.2 cm from the fundus to the ectocervix, 4.5 cm from cornu to cornu, and 3.7 cm from the anterior surface to the posterior surface. The cervix is 3.5 cm in length and up to 3.6 cm in diameter in the ectocervical region. The endocervix is 3.0 cm in length and lined by pink-tan soft rugose mucosa. The endometrial cavity measures 3.7 cm in length and up to 2.4 cm in width. The right fallopian tube is fimbriated at one end and measures 6.0 cm in length and 0.4 cm in diameter with an unremarkable lumen up to 0.2 cm in diameter. The left fallopian tube is fimbriated at one end and measures 5.5 cm in length and 0.4 cm in diameter with an unremarkable lumen up to 0.2 cm in diameter.

Focal roughening of the serosal surface is noted with a fibrinous appearance. No distinct tumor involvement is seen. The cervical and endometrial mucosa is pink-tan soft and grossly unremarkable. The transformation zone is distinct. No leiomyomas are present. No masses are seen. Representative sections are submitted.

H1. Anterior cervix - 1

H2. Posterior cervix - 1

H3. Anterior uterine corpus - 1

H4. Posterior uterine corpus - 1

H5. Serosal adhesions - 2

H6. Right fallopian tube - 3

H7. Left fallopian tube - 3

I. ANTERIOR PERITONEUM

Labeled with the patient's name, labeled "anterior peritoneum", and received in formalin are two portions of pink-tan soft tissue measuring 2.0 and 2.2 cm in greatest dimension. Sectioning reveals focal gray-white friable tumor. Representative sections are submitted.

I1. 3

J. RIGHT GUTTER

Labeled with the patient's name, labeled "right gutter", and received in formalin is an aggregate of pink-tan soft tissue fragments measuring 1.2 to 6.2 cm in greatest dimension and aggregating to 8.0 x 7.0 x 1.5 cm. Cut surfaces reveal extensive gray-white firm tumor. Representative sections are submitted.

J1. 2

[page 4 of 4]
PATH #:

K. FALCIFORM LIGAMENT

Labeled with the patient's name, labeled "falciform ligament", and received in formalin is a portion of pink-tan soft tissue measuring 3.0 x 2.1 x 1.5 cm. Sectioning reveals focal gray-white firm tumor. Representative sections are submitted.

K1. 2

Gross dictated by _____

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

FROZEN SECTION 1 PART B:

- High-grade carcinoma.

OPERATIVE CONSULT (GROSS):

PART H: GROSS ONLY:

- No mass seen on endometrial cavity or fallopian tubes.

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by

Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
lectronically signed _____

Source: NCI Genomic Data Commons file d00cb69d-5459-4b31-923e-0486ba5890cd (TCGA-23-1029.89E1F403-12CB-442A-9588-CF5C0AC0E0A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).